Somatic mutation profile of tumor specimen TARGET-40-0A4I4O-01A (aliquot TARGET-40-0A4I4O-01A-01D) from TARGET case TARGET-40-0A4I4O, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 32.4 years (11,828 days).
Specimen TARGET-40-0A4I4O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af669fcb-e0eb-4675-ad78-6321bf582d42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4I4O-10A (Blood Derived Normal), aliquot TARGET-40-0A4I4O-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81f1e3be-00ac-416e-aa40-3aeb53a5cb5d

The open-access MAF lists 27 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Intron 3, RNA 2, Frame Shift Del 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.3595G>T p.D1199Y (on ENST00000404938 / NM_001163941.2; = p.D754Y on NM_178559.6) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV51724374; called by muse, mutect2
- AZGP1 | c.770A>G p.N257S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772849436, COSV52797632; called by mutect2, varscan2
- AZGP1 | c.769A>G p.N257D | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs762922073, COSV52797639; called by mutect2, varscan2
- CPLX4 | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as rs370860769; called by muse, varscan2
- CSMD3 | c.2593A>T p.I865F (on ENST00000297405 / NM_001363185.1; = p.I761F on NM_052900.3) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52156925; called by mutect2, varscan2
- CYP1A1 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs1380427518; called by muse, mutect2, varscan2
- MAP3K5 | c.893G>C p.R298T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100753026; called by muse, mutect2, varscan2
- MET | c.869C>A p.S290Y | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV59261351; called by muse, mutect2, varscan2
- OCA2 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV100668567; called by muse, mutect2, varscan2
- OR10K2 | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs764388026, COSV59220440, COSV59222447; called by muse, mutect2
- APEX2 | c.1223C>A p.P408H | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0.04); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- CLSTN3 | c.2464C>T p.R822C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.39); called by mutect2, varscan2
- DHX8 | c.1829G>C p.R610T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- EGF | c.1142del p.T381Sfs*4 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- TRAF6 | c.1087C>A p.H363N | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- DAP | c.183G>A p.G61= | Silent (SNP) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- LAMA2 | c.6264G>A p.K2088= | Silent (SNP) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- MCF2L | c.1971C>T p.Y657= (on ENST00000375608; = p.Y625= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs368629853; called by muse, mutect2, varscan2
- RSPH4A | c.1488C>T p.H496= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs367598099; ClinVar: likely benign; called by mutect2, varscan2
- SLC4A10 | c.333A>G p.E111= | Silent (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- EGF | c.3174-21C>G | Intron (SNP) | VAF 12/38 reads (32%) | called by muse, mutect2, varscan2
- FAM27E5 | n.352C>A | RNA (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- MIR516A2 | chr19:53762462 T>C | 3'Flank (SNP) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- RTN1 | c.1974-32C>T | Intron (SNP) | VAF 10/16 reads (63%) | catalogued as rs375257603; called by muse, varscan2
- TAS2R7 | c.*28del | 3'UTR (DEL) | VAF 22/75 reads (29%) | called by mutect2, varscan2
- TTN | c.34523-895C>G | Intron (SNP) | VAF 16/32 reads (50%) | called by muse, varscan2
- VPS35P1 | n.184C>A | RNA (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
